Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A6M5, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A6M5-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report
Temporary Copy

Page 1 of 3

Case:
Collected:
Ordered by:

Patient:
ID:
Location:

ACCESSION

Submitting Physician

Clinical History

Liver mass

Diagnosis

1. "HEPATIC LYMPH NODE", (BIOPSY):
- ONE LYMPH NODE IS IDENTIFIED AND IS FREE OF METASTATIC DISEASE (0/1)
2. "CELIAC LYMPH NODE", (DISSECTION):
- NINE LYMPH NODES ARE IDENTIFIED AND ARE FREE OF METASTATIC DISEASE (0/9)
3. "PERIAORTIC LYMPH NODE", (BIOPSY):
- ONE LYMPH NODE IS IDENTIFIED AND IS POSITIVE FOR METASTATIC DISEASE (1/1)
4. "RETROPORTAL LYMPH NODE", (BIOPSY):
- ONE LYMPH NODE IS IDENTIFIED AND IS FREE OF METASTATIC DISEASE (0/1)
5. "LIVER, LEFT LOBE", (LOBECTOMY):
- HEPATOCELLULAR CARCINOMA, FIBROLAMELLAR VARIANT
- SEE SYNOPSIS REPORT

ICD-O-3

*Carcinoma, hepatocellular
fibrolamellar 8711/3*

Site Liver C22.0

JAS 7/24/10

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

electronic signature

Department of Pathology

For questions regarding this case, call

Resident

Gross Description

This case consists of five specimens, each received in formalin labeled with the patient's name and medical record number.

Specimen one is received labeled "common hepatic lymph node", and consists of a single candidate lymph node "2.0 x 0.8 x 0.8" resected in continuity with benign appearing fat. This tissue is submitted in its entirety in cassette 1A-1D.

[page 2 of 3]
Surg Path Final Report
Temporary Copy

Case: [REDACTED]
Collected: [REDACTED]
Ordered by: [REDACTED]

Page 2 of 3

Patient: [REDACTED]
ID: [REDACTED]
Location: [REDACTED]

Specimen two is received labeled "celiac lymph node", and consists of a single fragment of red-tan fibrous tissue (2.5 x 1.8 x 0.5 cm). This tissue is submitted in its entirety in cassettes 2A-2B.

Specimen three is received labeled "periaortic lymph node", and consists of a single reddish tan fragment of soft tissue (2.5 x 1.8 x 0.6 cm). Tissue is bivalved and submitted in cassette 3A.

Specimen four is received labeled "retroportal lymph node", and consists of a single candidate lymph node (1.2 x 0.8 x 0.8) which is bivalved and submitted in its entirety in cassette 4A.

Specimen five is received labeled "left lobectomy", and consists of a 600 g segment of liver (12.5 x 12.5 x 7.0 cm). A cauterized surgical margin is noted. The resection specimen is dominated by a large firm nodular lesion (10.0 x 6.5 x 7.0 cm). This nodular mass approaches the surgical margin to within 2.0 cm. The surgical margin is inked black, and the exterior surface of the liver capsule adjacent to the nodular mass is inked blue. Sectioning reveals the mass to abut the capsule. Penetration is not seen. The mass is notable for a large central scar stellate pattern and bile type staining peripherally. Tissue is submitted as follows: 5A central scar portion of mass; 5B representative section of tumor; 5C tumor interface with normal parenchyma; 5D representative section of liver tumor; 5E tumor to resection margins; 5F tumor to resection margins; 5G representative sections of uninvolved liver parenchyma; 5H-5K additional representative sections of tumor mass.

Microscopic Examination

Performed.

Synoptic Report

Based on AJCC/UICC TNM, 7th edition
Protocol web posting date:

Specimen:

Liver

Procedure:

Partial hepatectomy

Tumor size:

Greatest dimension: 10.0 cm

*Additional dimensions: 6.5 x 7.0 cm

Tumor focality:

Solitary

Histologic type:

Hepatocellular carcinoma, fibrolamellar variant

Histologic grade:

G2

Tumor extension:

Tumor involves, but does not perforate, the visceral peritoneum (Glisson capsule).

Margins:

Uninvolved by invasive carcinoma.

Distance of invasive carcinoma from closest margin: 1.3 cm (parenchymal margin).

Macroscopic venous invasion: Not identified.

Microscopic small vessel invasion: Not identified.

Pathologic staging (pTNM):

Primary tumor (pT): pT1

[page 3 of 3]
Surg Path Final Report
Temporary Copy

Page 3 of 3

Case

Patient

Collected

ID

Ordered by

Location

Regional lymph nodes (pN): pN1

Number of lymph nodes examined: 12

Number of lymph nodes involved: 1

Distant metastasis (pM): Not applicable

Additional pathologic findings: The background liver parenchyma is unremarkable. Special histochemical stains trichrome, PAS-D, and iron are performed on a representative tissue block of uninvolved liver with appropriate controls and show no evidence of pathologic fibrosis, iron deposition, or alpha-1-antitrypsin type hyaline globules.

Pathologic Discrepancy		☒
Primary Malignancy History		☒
Discrepancy in Primary Malignancy		☒
Case ID (circle)	QU-1050	DISQUALIFIED

Source: NCI Genomic Data Commons file bbfa34f8-24e5-44c5-b571-83e692f9ae0f (TCGA-RC-A6M5.CFE4CEBF-2B23-4ABD-8F50-2B7C4A432AA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).